Somatic mutation profile of tumor specimen TCGA-DD-A4NI-01A (aliquot TCGA-DD-A4NI-01A-11D-A27I-10) from TCGA case TCGA-DD-A4NI, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 67.1 years (24,516 days).
Specimen TCGA-DD-A4NI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2f15943-fcc5-4286-8ef4-d7c1f1453e81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4NI-10A (Blood Derived Normal), aliquot TCGA-DD-A4NI-10A-01D-A27I-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fabf263-fc47-4813-8273-5d62ef4272c2

The open-access MAF lists 162 somatic variants for this specimen: 120 protein-altering or splice-affecting, 37 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 37, Splice Site 7, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 2, In Frame Del 2, 3'UTR 2, RNA 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.107A>C p.H36P | Missense Mutation (SNP) | VAF 79/265 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as COSV62688989, COSV62691224; called by muse, mutect2, varscan2
- AARS2 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 82/310 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55116348; called by muse, mutect2, varscan2
- ACSM2A | c.1510-1G>A p.X504_splice (on ENST00000219054; = p.X425_splice on NM_001308169.2) | Splice Site (SNP) | VAF 44/188 reads (23%) | catalogued as COSV54586996; called by muse, mutect2, varscan2
- ACTG1 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59511220; called by muse, mutect2, varscan2
- ACVR2A | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV54025591; called by muse, mutect2, varscan2
- ADGRD1 | c.2464A>G p.K822E | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV55450659; called by muse, mutect2, varscan2
- AKR1E2 | c.324+1G>T p.X108_splice | Splice Site (SNP) | VAF 53/252 reads (21%) | catalogued as COSV53630951; called by muse, mutect2, varscan2
- AP3B2 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV55611689; called by muse, mutect2, varscan2
- APOC3 | c.252C>G p.F84L | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0.075); catalogued as COSV52636112; called by muse, mutect2, varscan2
- ARHGEF11 | c.829T>G p.S277A | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV63814232; called by muse, mutect2, varscan2
- ARHGEF2 | c.1025G>A p.C342Y (on ENST00000361247 / NM_001162383.2; = p.C314Y on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV58113553; called by muse, mutect2
- ATG4B | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV60351854; called by muse, varscan2
- ATP13A5 | c.2374T>C p.C792R | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs760725199, COSV60871826; called by muse, mutect2, varscan2
- ATP9A | c.1428C>A p.N476K | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.454); catalogued as COSV100124906, COSV58768983; called by muse, mutect2, varscan2
- AUP1 | c.1129A>G p.K377E | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV57818019; called by muse, mutect2
- BBS7 | c.2074A>G p.K692E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV52657887; called by muse, mutect2, varscan2
- C3 | c.3160A>G p.T1054A | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV55576381; called by muse, mutect2, varscan2
- CADPS2 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV57373321; called by muse, mutect2, varscan2
- CAPRIN1 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs1484946756, COSV58221061; called by mutect2, varscan2
- CAPRIN2 | c.2762C>T p.T921I | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV51833893; called by muse, mutect2
- CCDC191 | c.815A>C p.K272T | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV55674102; called by muse, mutect2, varscan2
- CCDC91 | c.332A>G p.K111R | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.048); catalogued as COSV60344959; called by muse, mutect2, varscan2
- CCNQ | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.45); catalogued as COSV52344960; called by muse, varscan2
- CHM | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 107/171 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs201252021, CD022133, COSV62565610; called by muse, mutect2, varscan2
- CHST12 | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV51676656; called by muse, mutect2, varscan2
- COL5A2 | c.1835G>A p.G612E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66411642; called by muse, mutect2, varscan2
- DBN1 | c.1447G>T p.G483W | Missense Mutation (SNP) | VAF 78/193 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52791050; called by muse, mutect2, varscan2
- DCHS1 | c.4909G>A p.V1637I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV55038828; called by muse, mutect2, varscan2
- DGKH | c.1887G>T p.R629S | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV54936112; called by muse, mutect2, varscan2
- DHX30 | c.1945G>A p.A649T (on ENST00000445061 / NM_138615.3; = p.A610T on NM_014966.3) | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs753357583, COSV53136322; called by muse, mutect2
- DISP3 | c.2870T>G p.L957R | Missense Mutation (SNP) | VAF 112/378 reads (30%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.024); catalogued as COSV53832049; called by muse, varscan2
- DLEC1 | c.2244A>T p.K748N | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57302624; called by muse, mutect2, varscan2
- DOCK1 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV54748257; called by muse, mutect2, varscan2
- DOCK1 | c.4537G>T p.D1513Y | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV54748273; called by muse, mutect2, varscan2
- DSG4 | c.812A>C p.K271T | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as COSV57394294; called by muse, mutect2, varscan2
- EPRS1 | c.2141G>T p.G714V | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); catalogued as COSV65100207; called by muse, mutect2, varscan2
- FBN2 | c.3427T>C p.F1143L | Missense Mutation (SNP) | VAF 21/324 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.26); catalogued as COSV52527734; called by muse, mutect2
- FCRL5 | c.1982T>A p.L661H | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62517206; called by muse, mutect2
- FLRT2 | c.1941C>G p.Y647* | Nonsense Mutation (SNP) | VAF 6/92 reads (7%) | catalogued as COSV58145813; called by muse, mutect2
- GHITM | c.721T>C p.F241L | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV64538861; called by muse, mutect2, varscan2
- GPR135 | c.1255G>T p.G419C | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV67749719, COSV67749914; called by muse, mutect2, varscan2
- GRAMD4 | c.1633-2A>T p.X545_splice | Splice Site (SNP) | VAF 6/92 reads (7%) | catalogued as COSV63031249; called by muse, mutect2
- H1-5 | c.562A>G p.K188E | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.17); catalogued as rs745570564, COSV58900708; called by muse, mutect2, varscan2
- HDAC9 | c.1451T>A p.M484K | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV67778737; called by muse, mutect2, varscan2
- HIBCH | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs1430906931, COSV62892324; called by muse, mutect2
- HK3 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs753665029, COSV52842269; called by muse, mutect2
- HYDIN | c.13936A>G p.T4646A | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV101125187; called by muse, mutect2, varscan2
- ITGB5 | c.152A>G p.K51R | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV56150890, COSV56151728; called by muse, mutect2
- ITIH1 | c.2479A>G p.T827A | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.955); catalogued as COSV56256561; called by muse, mutect2, varscan2
- KBTBD7 | c.1679A>G p.Q560R | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs754279461, COSV65266853; called by muse, mutect2, varscan2
- KIF19 | c.902G>T p.S301I | Missense Mutation (SNP) | VAF 149/269 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63429955; called by muse, mutect2, varscan2
- KLF15 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56180337, COSV56180526; called by muse, mutect2, varscan2
- NEFH | c.1817C>A p.S606Y | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV60218681; called by muse, mutect2, varscan2
- NFASC | c.3126G>C p.E1042D | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV58371921; called by muse, mutect2
- NGEF | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 4/100 reads (4%) | catalogued as COSV50916560; called by muse, mutect2
- NKX3-1 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV66511756; called by muse, mutect2, varscan2
- NLRP3 | c.2558A>G p.H853R | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV60228234; called by muse, mutect2, varscan2
- NRROS | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs1314586426, COSV60746757; called by muse, mutect2, varscan2
- NUDT12 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV50091755; called by muse, mutect2, varscan2
- NUFIP1 | c.204del p.M69Wfs*134 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs765016323; called by mutect2, pindel
- NUP93 | c.1588C>T p.R530W | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs750107617, COSV57432122; called by muse, mutect2, varscan2
- OLIG3 | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV62988842; called by muse, mutect2
- OR13C8 | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100623026, COSV58611693; called by muse, mutect2, varscan2
- OR1C1 | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.028); catalogued as COSV68715983; called by muse, mutect2, varscan2
- OR2Y1 | c.338T>G p.V113G | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV57137402; called by muse, mutect2
- PCDHGC3 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 24/269 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52758290, COSV52774105; called by muse, mutect2
- PDCL2 | c.604A>T p.I202L | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.268); catalogued as COSV55261558; called by muse, mutect2, varscan2
- PER1 | c.2512A>G p.K838E | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as COSV57920850; called by muse, mutect2
- PFKFB2 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 6/86 reads (7%) | PolyPhen possibly damaging (0.667); catalogued as COSV65548831; called by muse, mutect2
- PIK3C2A | c.2802G>A p.W934* | Nonsense Mutation (SNP) | VAF 36/105 reads (34%) | catalogued as COSV56404757; called by muse, mutect2, varscan2
- PLCE1 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV53360181; called by muse, mutect2
- PRSS1 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 59/385 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61194578; called by muse, mutect2, varscan2
- PSKH1 | c.850G>T p.G284C | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52124159; called by muse, mutect2, varscan2
- PSMC2 | c.53A>C p.D18A | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV50792097; called by muse, mutect2, varscan2
- PTP4A3 | c.161A>T p.D54V | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV61472282; called by muse, mutect2, varscan2
- PTPN9 | c.969-2A>T p.X323_splice | Splice Site (SNP) | VAF 25/106 reads (24%) | catalogued as COSV60724739; called by muse, mutect2, varscan2
- RAC2 | c.347A>G p.K116R | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs978951259, COSV99969616; called by muse, mutect2
- RNF31 | c.710G>T p.C237F | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53760457, COSV99396068; called by muse, mutect2, varscan2
- ROR2 | c.743C>G p.P248R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV65219358, COSV65221313; called by muse, mutect2
- RPRD1A | c.868T>C p.S290P | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs758740817, COSV61361738; called by muse, mutect2, varscan2
- RXRA | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.06); catalogued as COSV62684744; called by muse, mutect2, varscan2
- RYR3 | c.988T>A p.L330I | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.101); catalogued as COSV66799895; called by muse, mutect2, varscan2
- SARS2 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV55500498; called by muse, mutect2, varscan2
- SCAPER | c.2438G>C p.G813A | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV57745918; called by muse, mutect2, varscan2
- SCN5A | c.2851G>A p.D951N | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV61122665; called by muse, mutect2
- SDK1 | c.2881A>T p.T961S | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV67378658; called by muse, mutect2
- SERPINC1 | c.624+1G>A p.X208_splice | Splice Site (SNP) | VAF 68/167 reads (41%) | catalogued as CS126235, COSV62929976; called by muse, mutect2, varscan2
- SEZ6L | c.1614C>A p.N538K | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as COSV50670687; called by muse, mutect2, varscan2
- SHC4 | c.372C>A p.D124E | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV60114307; called by muse, mutect2, varscan2
- SLC12A1 | c.1299A>G p.V433= | Splice Region (SNP) | VAF 53/150 reads (35%) | catalogued as COSV57710605; called by muse, mutect2, varscan2
- SLC18A2 | c.320T>C p.V107A | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV53691998; called by muse, mutect2, varscan2
- SLC22A8 | c.437+1G>T p.X146_splice | Splice Site (SNP) | VAF 8/178 reads (4%) | catalogued as COSV60325960; called by muse, mutect2
- SOS1 | c.1642A>G p.S548G | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as CM070280, COSV67676406; called by muse, mutect2, varscan2
- SPI1 | c.232C>A p.P78T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs772416102, COSV57046707; called by muse, mutect2, varscan2
- SUN1 | c.2062T>G p.F688V (on ENST00000405266 / NM_001367651.1; = p.F568V on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV67450239, COSV67450802; called by muse, mutect2, varscan2
- SUPT6H | c.4058G>A p.G1353D | Missense Mutation (SNP) | VAF 84/245 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58929321; called by muse, mutect2, varscan2
- SYNPR | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1002535187, COSV55727774, COSV99888293; called by muse, mutect2, varscan2
- SYT5 | c.559G>T p.G187W | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62830280, COSV62830837; called by muse, mutect2, varscan2
- TEX2 | c.2647T>A p.F883I (on ENST00000583097 / NM_001288733.2; = p.F890I on NM_018469.5) | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.588); catalogued as COSV51983277; called by muse, mutect2, varscan2
- TEX26 | c.845G>A p.C282Y | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV66840260; called by muse, mutect2, varscan2
- TGFB1I1 | c.822C>A p.F274L (on ENST00000394863 / NM_001042454.3; = p.F257L on NM_015927.4) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs1214430699, COSV62357174, COSV62358647; called by muse, mutect2, varscan2
- THSD7B | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 82/321 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as rs756885295, COSV55657264; called by muse, mutect2, varscan2
- TNRC6A | c.5690T>G p.L1897R | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.121); catalogued as COSV59367256; called by muse, mutect2, varscan2
- TNXB | c.6793C>G p.L2265V (on ENST00000647633; = p.L2018V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.175); catalogued as COSV64483200; called by muse, mutect2, varscan2
- TUBB4A | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.403); catalogued as COSV51164090, COSV99900116; called by muse, mutect2, varscan2
- UPF3A | c.631+2T>C p.X211_splice | Splice Site (SNP) | VAF 22/232 reads (9%) | catalogued as COSV60895521; called by muse, mutect2
- USH2A | c.8822T>C p.I2941T | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV56398594; called by muse, mutect2
- USH2A | c.3982G>A p.G1328S | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.61); catalogued as COSV56398618; called by muse, mutect2
- USP17L2 | c.902T>C p.L301P | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs528142888, COSV61556202; called by muse, mutect2
- XPO6 | c.677G>A p.S226N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV58968580; called by mutect2, varscan2
- ZAN | c.4724G>T p.R1575M | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV61811787; called by muse, mutect2, varscan2
- ZBTB4 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.449); catalogued as rs1237090541, COSV60981551; called by muse, mutect2, varscan2
- ZNF518A | c.1238G>A p.G413D | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV60152191; called by muse, mutect2, varscan2
- ALB | c.1456_1458del p.V486del | In Frame Del (DEL) | VAF 16/90 reads (18%) | called by mutect2, pindel, varscan2
- ANKFY1 | c.1820_1832del p.Q607Lfs*38 | Frame Shift Del (DEL) | VAF 21/85 reads (25%) | called by mutect2, pindel, varscan2
- CHD1L | c.1862dup p.G623Rfs*47 | Frame Shift Ins (INS) | VAF 34/323 reads (11%) | called by mutect2, pindel, varscan2
- IGHV1-2 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 212/622 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- NCOA3 | c.362del p.L121Wfs*8 | Frame Shift Del (DEL) | VAF 73/209 reads (35%) | called by mutect2, varscan2
- NUP133 | c.2700dup p.L901Sfs*33 | Frame Shift Ins (INS) | VAF 28/119 reads (24%) | called by mutect2, pindel, varscan2
- PECR | c.68_91del p.V23_I30del | In Frame Del (DEL) | VAF 54/195 reads (28%) | called by mutect2, pindel, varscan2
- ACCSL | c.732T>A p.S244= | Silent (SNP) | VAF 10/233 reads (4%) | catalogued as COSV66581882; called by muse, mutect2
- ATP8A2 | c.3444C>A p.G1148= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as COSV54963591; called by muse, mutect2, varscan2
- C1QTNF2 | c.24G>T p.P8= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV67433002; called by muse, mutect2
- CEP76 | c.315G>A p.R105= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV50867717; called by muse, mutect2, varscan2
- CHAT | c.1749C>T p.A583= | Silent (SNP) | VAF 60/180 reads (33%) | catalogued as rs201580702, COSV60328568; called by muse, mutect2, varscan2
- CYP4F2 | c.822G>A p.R274= | Silent (SNP) | VAF 101/243 reads (42%) | catalogued as COSV50001951; called by muse, mutect2, varscan2
- DCLK2 | c.1815C>A p.I605= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV56207874; called by muse, mutect2, varscan2
- DSG2 | c.1299T>C p.D433= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs367548984; ClinVar: likely benign; called by muse, mutect2, varscan2
- EML3 | c.897A>G p.R299= | Silent (SNP) | VAF 34/127 reads (27%) | catalogued as COSV53883371; called by muse, mutect2, varscan2
- GALNT6 | c.876G>A p.V292= | Silent (SNP) | VAF 60/198 reads (30%) | catalogued as COSV62542688; called by muse, mutect2, varscan2
- GPR19 | c.36A>G p.P12= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV60124079; called by muse, mutect2, varscan2
- IGF2BP3 | c.1413T>C p.Y471= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as COSV51688699; called by muse, mutect2, varscan2
- IL1RL2 | c.918A>G p.K306= | Silent (SNP) | VAF 59/142 reads (42%) | catalogued as rs1388584938, COSV51816882; called by muse, mutect2, varscan2
- KCNG4 | c.99G>T p.T33= | Silent (SNP) | VAF 41/123 reads (33%) | catalogued as COSV57584887; called by muse, mutect2, varscan2
- KRT3 | c.468C>T p.G156= | Silent (SNP) | VAF 58/154 reads (38%) | catalogued as COSV58816282; called by muse, mutect2, varscan2
- LENG8 | c.1474C>A p.R492= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV58729022; called by muse, mutect2, varscan2
- LTBP1 | c.591T>C p.N197= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV63192230; called by muse, mutect2
- MARCHF6 | c.1215T>A p.T405= | Silent (SNP) | VAF 11/172 reads (6%) | catalogued as COSV56883852; called by muse, mutect2
- MYBBP1A | c.2757C>T p.T919= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as rs769485013, COSV54594592; ClinVar: likely benign; called by muse, mutect2
- NFYA | c.120G>A p.Q40= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as rs771405179, COSV58199203; called by muse, mutect2, varscan2
- NPL | c.771C>G p.V257= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV51125109; called by muse, mutect2
- NRXN1 | c.3456G>T p.L1152= | Silent (SNP) | VAF 62/236 reads (26%) | catalogued as COSV58458273; called by muse, mutect2, varscan2
- OBSL1 | c.1407G>T p.P469= | Silent (SNP) | VAF 101/254 reads (40%) | catalogued as COSV54714593, COSV54724589; called by muse, mutect2, varscan2
- PARP14 | c.1284A>T p.T428= | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as COSV71735129; called by muse, mutect2, varscan2
- PTPRB | c.777G>A p.G259= | Silent (SNP) | VAF 74/268 reads (28%) | catalogued as COSV54246699; called by muse, mutect2, varscan2
- QRFPR | c.99G>C p.P33= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV57678558; called by muse, mutect2, varscan2
- RASGRF1 | c.405G>A p.E135= | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as rs763522325, COSV69180991; called by muse, mutect2, varscan2
- SEMA3A | c.759T>C p.D253= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as COSV54878312; called by muse, mutect2, varscan2
- SLC24A2 | c.1563G>A p.A521= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as rs201117303, COSV53859015; called by muse, mutect2, varscan2
- SNRPN | c.207G>T p.L69= | Silent (SNP) | VAF 7/155 reads (5%) | catalogued as COSV57594786; called by muse, mutect2
- SYNE2 | c.2355A>G p.A785= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as COSV59958373; called by muse, mutect2, varscan2
- TBX20 | c.1200G>T p.S400= | Silent (SNP) | VAF 90/398 reads (23%) | catalogued as rs541075247, COSV68784574; called by muse, mutect2, varscan2
- TRIP12 | c.5811A>T p.T1937= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs750607517, COSV52268078; called by muse, mutect2, varscan2
- TUBB4A | c.1317G>C p.A439= | Silent (SNP) | VAF 35/150 reads (23%) | catalogued as COSV99900117; called by muse, mutect2, varscan2
- WIZ | c.4149C>T p.G1383= (on ENST00000673675 / NM_001371589.1; = p.G288= on NM_021241.3) | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV54609743; called by muse, mutect2, varscan2
- ZC3H10 | c.891C>T p.P297= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as rs1246515674, COSV57769533; called by muse, mutect2, varscan2
- ZNF180 | c.1782A>T p.V594= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV55422455; called by muse, mutect2, varscan2
- GANC | c.*2287A>G | 3'UTR (SNP) | VAF 102/260 reads (39%) | catalogued as COSV58810204; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.805G>A | RNA (SNP) | VAF 25/48 reads (52%) | catalogued as rs368429459; called by muse, mutect2, varscan2
- NXF5 | n.934C>G | RNA (SNP) | VAF 42/226 reads (19%) | catalogued as COSV53792122; called by muse, mutect2, varscan2
- TRIM61 | c.526-2177A>G | Intron (SNP) | VAF 106/344 reads (31%) | catalogued as COSV100256194; called by muse, varscan2
- TSPAN18 | c.*1773C>T | 3'UTR (SNP) | VAF 24/59 reads (41%) | catalogued as rs768001614, COSV100370957; called by muse, mutect2, varscan2
